Surgical pathology report (de-identified scan), TCGA case TCGA-CH-5753, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CH-5753-01A (Primary Tumor).

[page 1 of 2]
Diagnosis

1. Minimally to poorly differentiated multifocal adenocarcinoma of the prostate (Gleason 4+5=9). Gleason 5 = 20%. Maximum tumor diameter 1.7 cm. Tumor involves approx. 30% of total prostate. Tumor infiltration of left basolateral periprostatic fatty tissue (max. 1 mm deep). Tumor infiltration of the right seminal vesicle. Multifocal tumor involvement of perineural sheaths.

Foci of a prostatic intraepithelial neoplasia (high-grade PIN) and signs of myoglandular prostatic hyperplasia. Urothelium of prostatic urethra without dysplasia.

2. Right lymph nodes: two tumor-infiltrated lymph nodes (2/7).
3. Left lymph nodes: 3 tumor-free lymph nodes (0/3).

Tumor classification

pT3b, max. tumor diameter 17 mm, tumor involving approx. 30% of the total prostate, Gleason 4+5=9 (Gleason 5: 20%), pN1 (2/10)

Remark

The result of the prostate punch biopsy, Gleason 4+5=9, is confirmed by this finding. Since the status of the resection margin is unclear in the region of the right apex, further investigations will be conducted.

An additional immunohistological investigation will be carried out to establish whether there is any invasion of the vessels. The results will be presented in a follow-up report.

No evidence of the previously described mantle cell lymphoma could be detected in these findings from the investigation of the lymph nodes.

Follow-up report**Microscopy**

(HE, 1 tissue block, immunohistochemistry: AE1/AE3 and 2 further tissue blocks in each case immunohistochemistry: D240 and CD31.

In the meantime, further step sections and a supplementary immunohistochemical investigation were carried out with suspected tumor involvement of the surgical resection margin in the region of the right apex. Tumor cells here extend very nearly to the blue-labeled preparation margin. In view of the very marked thermal artifacts in this region, however, it is difficult to make any assessment here. Individual cytokeratin-positive cells have questionable contact with the blue-labeled resection margin, but no unequivocal evidence of tumor contact can be shown with absolute certainty even after additional investigations, so the R status must most likely be assumed to be R0.

The additional immunohistochemical investigation of two representative tumor blocks confirms the presence of a tumorous invasion of the lymph vessels. No signs of blood vessel invasion were found.

[page 2 of 2]
The final tumor classification is thus as follows:

pT3b, maximum tumor diameter 17 mm, tumor involves approx. 30% of the total prostate, Gleason 4+5=9 (Gleason 5: 20%), L1, V0, pN1 (2/10), R0.

Source: NCI Genomic Data Commons file a22676e9-bbb3-4fad-81fa-a45ff9025bfd (TCGA-CH-5753.4E86E7FC-A1C5-4D3B-A0B3-23187ADFD096.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).